Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAOU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAOU-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Female

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – skin from from trunk region, non-pigmented, surgical resection

Microscopic description:

Received material is ulcerated amelanotic melanoma measured Clark - IV, Breslow - 12mm. Stage II, T4. N0, M0.

Final diagnosis: Ulcerated amelanotic melanoma.

ICD O-3
Melanoma, amelanotic 8730/3
Site. Skin trunk 0445
C/S 4/22/14

Confidential

Source: NCI Genomic Data Commons file d93a3d7c-1bec-414d-a443-274e6b399b0a (TCGA-BF-AAOU.C4F6EF2D-447C-43CA-ADF8-88A511B05D77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).